Surgical pathology report (de-identified scan), TCGA case TCGA-QQ-A8VD, project TCGA-SARC (Sarcoma), tissue source site Roswell Park, specimen TCGA-QQ-A8VD-01A (Primary Tumor).

Date of surgery:

SPECIMEN(S): A. BX RIGHT UPPER ABDOMINAL WALL MASS

CLINICAL HISTORY:

None

PRE-OPERATIVE DIAGNOSIS:

Abdominal wall mass

FROZEN SECTION DIAGNOSIS:

A. BIOPSY RIGHT UPPER ABDOMINAL WALL MASS

Spindle cell tumor, called to Dr. by Dr at

ICD-O-3
Abdominal desmoid 8822/1.
Site: ^{case} Retroperitoneum C48.0
^{path} Abdominal wall NOS C49.4
JW 1/21/14

GROSS DESCRIPTION:

A. BIOPSY RIGHT UPPER ABDOMINAL WALL MASS

Received fresh in a container with the patient name labelled "biopsy of right abdominal wall mass" is a white tan fragment of soft tissue measuring 1.6x1.5x0.7cm. Bisected and submitted in toto in cassette A.

DIAGNOSIS:

ABDOMINAL WALL MASS, BIOPSY:

-FIBROMATOSIS, SEE NOTE

NOTE:

LESIONAL CELLS SHOW FOCI OF POSITIVITY FOR SMA AND HHF35 BUT ARE NEGATIVE FOR S-100, DESMIN AND CD117.

CONFERENCE CASE

ADDENDUM:

The lesion is Herceptin negative.

A small population (<5%) of the cells appear to express EGFR by immunohistochemistry.

Source: NCI Genomic Data Commons file 66816028-9f87-4cd8-b741-ad4980d123b0 (TCGA-QQ-A8VD.B48D3D28-347E-4933-9A9A-1BD843F84ED2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).